Somatic mutation profile of tumor specimen MMRF_1923_1_BM_CD138pos (aliquot MMRF_1923_1_BM_CD138pos_T1_KHS5U_L08855) from MMRF case MMRF_1923, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.0 years (19,366 days).
Specimen MMRF_1923_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 389e3f84-aa4a-4844-8fde-1255f33f821c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1923_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1923_1_PB_WBC_C2_KHS5U_L11059; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/676c18a9-1cf4-4708-b416-089744f4e5c5

The open-access MAF lists 85 somatic variants for this specimen: 33 protein-altering or splice-affecting, 13 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, 3'UTR 20, Silent 13, Intron 12, Frame Shift Del 4, 5'UTR 4, Nonsense Mutation 3, 5'Flank 3, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BMX | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs1446519223; called by muse, mutect2, varscan2
- CDK8 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV67423403; called by muse, mutect2
- CLDN24 | c.315G>C p.L105F | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.051); catalogued as rs1560906432; called by muse, mutect2
- COL4A1 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as rs570739274, COSV65421457; called by muse, mutect2, varscan2
- FAM83G | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1342040634; called by muse, mutect2
- FLG2 | c.15G>C p.L5F | Missense Mutation (SNP) | VAF 10/163 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101165934, COSV66166729; called by muse, mutect2
- KCNG4 | c.730C>G p.P244A | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV57585017; called by muse, mutect2, varscan2
- LRP1B | c.2663A>G p.D888G | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.089); catalogued as COSV100796616, COSV63341931; called by muse, mutect2, varscan2
- LRP6 | c.4487C>T p.S1496L | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV53790749; called by muse, mutect2
- MYCN | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55260389, COSV55261356; called by muse, mutect2
- PLXNA2 | c.2671G>A p.A891T | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.061); catalogued as rs769622910, COSV65443041; called by muse, mutect2, varscan2
- TNR | c.3709G>A p.A1237T | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.118); catalogued as rs753805387, COSV54898293; called by muse, mutect2, varscan2
- UGT2B7 | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1467570394; called by muse, mutect2, varscan2
- WDR36 | c.2534A>G p.N845S | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1406217849; called by muse, mutect2, varscan2
- ZNF420 | c.999A>C p.K333N | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58494369, COSV58495505; called by muse, mutect2, varscan2
- APOBEC4 | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 5/134 reads (4%) | called by muse, mutect2
- CDK8 | c.512T>G p.I171S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CDK8 | c.900_901del p.H300Qfs*3 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by mutect2, pindel
- CHD5 | c.3616G>C p.E1206Q | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CNST | c.222C>G p.S74R | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- DUSP2 | c.519_549del p.V174Afs*57 | Frame Shift Del (DEL) | VAF 10/73 reads (14%) | called by mutect2, pindel*
- IFNA1 | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | called by muse, mutect2, varscan2
- IGKV1D-43 | c.336G>T p.Q112H | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.168); called by muse, varscan2
- IGLV3-10 | c.224G>C p.G75A | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, varscan2
- KLHL38 | c.1344_1349dup p.I449_Q450insHI | In Frame Ins (INS) | VAF 19/85 reads (22%) | called by mutect2, pindel, varscan2
- LRRTM2 | c.1070T>C p.F357S | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MKRN2 | c.423G>C p.E141D | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.22); called by muse, mutect2
- MRC1 | c.1603G>T p.E535* | Nonsense Mutation (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- PATZ1 | c.679_682del p.P227Cfs*20 | Frame Shift Del (DEL) | VAF 11/72 reads (15%) | called by mutect2, pindel, varscan2
- PLA2G4A | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.455); called by muse, mutect2
- SLC16A2 | c.1244T>C p.V415A | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.81); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- SPG11 | c.1691T>C p.V564A | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF519 | c.773_776del p.I258Tfs*7 | Frame Shift Del (DEL) | VAF 25/80 reads (31%) | called by mutect2, pindel, varscan2
- ACSS2 | c.693C>T p.D231= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as rs769910327; called by muse, mutect2, varscan2
- ATL3 | c.1230C>T p.S410= | Silent (SNP) | VAF 10/121 reads (8%) | called by muse, mutect2
- DCAF4L2 | c.957C>A p.P319= | Silent (SNP) | VAF 21/85 reads (25%) | called by muse, mutect2, varscan2
- HGF | c.543A>G p.R181= | Silent (SNP) | VAF 22/115 reads (19%) | called by muse, mutect2, varscan2
- IGLV3-1 | c.252C>T p.N84= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as rs181381534; called by muse, mutect2, varscan2
- IRX2 | c.1290C>T p.D430= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs1017366902; called by muse, mutect2, varscan2
- KCNK16 | c.900C>T p.F300= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as COSV100949121; called by muse, mutect2, varscan2
- LRCH3 | c.2313G>A p.Q771= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as rs1246103211; called by muse, mutect2
- MTOR | c.444G>A p.E148= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as rs571699240; called by muse, mutect2, varscan2
- NUP205 | c.5538T>C p.L1846= | Silent (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2, varscan2
- PCDHA6 | c.2247G>A p.S749= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as COSV65343943; called by muse, mutect2
- RNF4 | c.231G>A p.R77= | Silent (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- STIM2 | c.2229G>A p.K743= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as rs762388940; called by mutect2, varscan2
- AC024598.1 | c.*670G>C | 3'UTR (SNP) | VAF 21/55 reads (38%) | catalogued as COSV60824471; called by muse, mutect2, varscan2
- ADH5P5 | chr5:23980111 T>G | 5'Flank (SNP) | VAF 19/51 reads (37%) | catalogued as rs1260631458; called by muse, mutect2, varscan2
- AQP2 | c.*244T>C | 3'UTR (SNP) | VAF 5/66 reads (8%) | called by muse, mutect2
- ARIH2 | c.*307A>G | 3'UTR (SNP) | VAF 15/49 reads (31%) | called by muse, mutect2, varscan2
- ARL14EP | c.*739C>G | 3'UTR (SNP) | VAF 8/51 reads (16%) | catalogued as rs914191397; called by muse, mutect2, varscan2
- ATR | c.6078+86A>G | Intron (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2, varscan2
- BRPF1 | c.3188-49G>A | Intron (SNP) | VAF 14/94 reads (15%) | catalogued as rs779005594; called by muse, mutect2, varscan2
- CDK19 | c.*3820G>C | 3'UTR (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- CHORDC1 | c.493-1504_493-1503insG | Intron (INS) | VAF 4/14 reads (29%) | catalogued as rs1453438692; called by mutect2, varscan2
- DACT2 | c.*136C>T | 3'UTR (SNP) | VAF 7/62 reads (11%) | catalogued as rs909284784; called by muse, mutect2, varscan2
- DAW1 | chr2:227871417 G>A | 5'Flank (SNP) | VAF 8/33 reads (24%) | catalogued as rs1454470032; called by muse, mutect2, varscan2
- ERICH1 | c.1258+1023G>A | Intron (SNP) | VAF 16/91 reads (18%) | called by muse, mutect2, varscan2
- FN1 | c.*1066C>T | 3'UTR (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- FOSL2 | c.*2004G>A | 3'UTR (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- GBX2 | c.*664G>A | 3'UTR (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- ISCU | c.419-468C>G | Intron (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2, varscan2
- ISCU | c.419-467C>T | Intron (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2, varscan2
- KCNK5 | c.-99C>A | 5'UTR (SNP) | VAF 6/81 reads (7%) | called by muse, mutect2
- KIAA1841 | c.1837-85A>G | Intron (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- LRFN5 | c.*129G>T | 3'UTR (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2, varscan2
- MAU2 | c.1156-119G>A | Intron (SNP) | VAF 11/40 reads (28%) | catalogued as rs1055043009; called by muse, mutect2, varscan2
- MMP11 | c.1075+36C>A | Intron (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- NHSL1 | c.*1045T>G | 3'UTR (SNP) | VAF 15/55 reads (27%) | called by muse, mutect2, varscan2
- NRM | c.-103C>T | 5'UTR (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2, varscan2
- PGAP1 | c.*2892A>T | 3'UTR (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2, varscan2
- PPP2R2D | c.*156G>A | 3'UTR (SNP) | VAF 3/46 reads (7%) | catalogued as rs1369234555, COSV70778837; called by muse, mutect2
- RAB39B | c.-113G>A | 5'UTR (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- RABGGTA | c.1467+54T>A | Intron (SNP) | VAF 22/107 reads (21%) | called by muse, mutect2, varscan2
- RABGGTA | c.1467+53C>T | Intron (SNP) | VAF 21/105 reads (20%) | catalogued as rs1244841512; called by muse, mutect2, varscan2
- RASGEF1B | c.438+3522C>A | Intron (SNP) | VAF 11/43 reads (26%) | called by muse, mutect2, varscan2
- RBIS | chr8:85222483 G>A | 5'Flank (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- RPS23 | c.*1580C>T | 3'UTR (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- SEMA3E | c.*1817A>C | 3'UTR (SNP) | VAF 10/56 reads (18%) | catalogued as rs1562744919; called by muse, mutect2, varscan2
- SLC19A3 | c.*584T>C | 3'UTR (SNP) | VAF 10/37 reads (27%) | called by muse, mutect2, varscan2
- SLC25A31 | c.-124G>A | 5'UTR (SNP) | VAF 5/97 reads (5%) | catalogued as rs1398317892, COSV55418622; called by muse, mutect2
- SUSD5 | c.*2228C>T | 3'UTR (SNP) | VAF 12/68 reads (18%) | called by mutect2, varscan2
- TMEM33 | c.*4836G>A | 3'UTR (SNP) | VAF 10/100 reads (10%) | catalogued as rs777938440; called by muse, mutect2
- VCPIP1 | c.*524A>G | 3'UTR (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- ZNF3 | c.*621C>T | 3'UTR (SNP) | VAF 27/88 reads (31%) | called by muse, mutect2, varscan2
